Surgical pathology report (de-identified scan), TCGA case TCGA-CS-4943, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-4943-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

[REDACTED] TCGA - CS - 4943

1. Research: specimen not received
2. Primary tumor consistent with glioma: anaplastic astrocytoma, grade III (WHO scale), see microscopic description, see comment
3. Research: specimen not received
4. SPECIMEN NOT RECEIVED: specimen not received
5. Primary tumor for permanent: anaplastic astrocytoma, grade III (WHO scale), see microscopic description, see comment.

Comment:

[REDACTED] reviewed selected slides and concurs with the presence of malignancy in this material.

[REDACTED]

Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of a moderately pleomorphic and infiltrative proliferation of astrocytes. There are many easily identified mitoses. There is no microvascular proliferation or necrosis. The findings are diagnostic of an anaplastic astrocytoma, grade III of IV (WHO scale).

Frozen Section Diagnosis:

- [REDACTED]
2. Primary tumor consistent with glioma: High-grade glioma

[page 2 of 3]
[REDACTED]

Clinical History and Diagnosis:
Left frontal tumor

Source of Specimen:

- 1: Research
- 2: Primary tumor consistent with glioma
- 3: Research
- 4: SPECIMEN NOT RECEIVED
- 5: Primary tumor for permanent

[REDACTED]
[REDACTED]
[REDACTED]

1. Research:

2. Primary tumor consistent with glioma: Received fresh for frozen section, in a specimen container labeled with the patient's name and "#2 primary tumor consistent with glioma", is a 2 x 1.5 x 0.5 cm aggregate of soft tan-pink tissue. Approximately 50% of the specimen is submitted for frozen section analysis. Touch preparations are made. The remainder of the specimen is entirely submitted in 2 cassettes as follows:

- A. Frozen section control
- B. remainder specimen

3. Research:

4. SPECIMEN NOT RECEIVED:

5. Primary tumor for permanent: Received in formalin, in a specimen container labeled with the patient's name and "#5 primary tumor for permanent", is a 4 x 4 x 1 cm aggregate of soft tan-pink tissue. The entire specimen is submitted in 4 cassettes.

[page 3 of 3]
[REDACTED]

Histology Laboratory
H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of [REDACTED]
[REDACTED]

[REDACTED] Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.
[REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED]
[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file ed7e03fa-c7ce-4bfc-af4a-34a1efcae990 (TCGA-CS-4943.C7CBBDB2-8EC4-4E6E-836E-2577CDA328DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).